Gene-level copy-number profile of tumor specimen AP-HMFR-8U from APOLLO case AP-HMFR, project APOLLO-LUAD (APOLLO1: Proteogenomic characterization of lung adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Solid carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3.
Specimen AP-HMFR-8U: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a4f76161-8862-48c6-b458-5eff7df981fe.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator AP-HMFR-WT (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,252 have no estimate.
https://portal.gdc.cancer.gov/files/3b973e4b-15cc-4ea4-a11d-1f5ac7b84604

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 95; copy number 1: 12,575; copy number 2: 34,197; copy number 3: 9,761; copy number 4: 1,078; copy number 5: 461; copy number 6: 138; copy number 7: 66.

Homozygous deletions (total copy number 0; autosomes only): 95 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:109,176,438–109,723,273, 12 genes (within-gene range 0–2): AC063923.2, LINC00488, RNU6-1236P, AC063923.1, DPPA2, Metazoa_SRP, DPPA4, AC124945.1, AC092905.1, H3P12, LINC01205, PPIAP15.
- chr4:49,579,833–49,589,529, 2 genes: AC119751.4, SNX18P25.
- chr6:73,209,746–73,653,992, 24 genes (within-gene range 0–1): AL365232.1, KHDC1L, KHDC1, AC019205.1, RPSAP41, EIF3EP1, SDCBP2P1, PAICSP3, DPPA5, KHDC3L, OOEP, OOEP-AS1, RPL39P3, RPS6P8, DDX43, CGAS, MTO1, RNU6-975P, RN7SL827P, EEF1A1, AL121972.1, AL603910.1, SLC17A5, RPS27P15.
- chr7:62,275,361–62,275,678, 1 gene: AC128676.1.
- chr9:40,481,558–40,883,763, 10 genes: AQP7P5, FP885919.1, AMYH02020865.1, BMS1P14, FP325318.1, IGKV1OR9-2, AL353626.3, RNU6-156P, AL353626.1, AL353626.2.
- chr12:37,575,587–38,087,392, 3 genes: ZNF970P, AK6P2, CLUHP8.
- chr13:19,674,752–19,865,048, 6 genes (within-gene range 0–1): PSPC1, RN7SL166P, ST6GALNAC4P1, ZMYM5, AL355001.1, AL355001.2.
- chr13:40,727,828–41,288,320, 22 genes: MIR320D1, MRPS31, Metazoa_SRP, SLC25A15, MIR621, TPTE2P5, CYCSP34, AL590064.1, SUGT1P3, ELF1, RGS17P1, WBP4, MIR3168, RN7SL597P, KBTBD6, AL354696.2, CALM2P3, KBTBD7, MORF4L1P4, MTRF1, AL354696.1, RAC1P3.
- chr13:95,310,830–95,394,454, 3 genes: RNY3P8, RNY4P27, MEMO1P5.
- chr21:12,999,676–13,016,692, 1 gene: AP001464.1.
- chr21:36,131,767–36,419,015, 11 genes (within-gene range 0–1): CBR3-AS1, RPS9P1, CBR3, DOP1B, RPL3P1, SRSF9P1, AP000692.2, MORC3, AP000692.1, CHAF1B, ATP5MFP1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 665 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:23,730,588–36,697,867, 181 genes, copy number 5–6 (broad region; genes not listed).
- chr14:21,563,819–38,371,338, 484 genes, copy number 5–7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 12,205. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
